Gene-level copy-number profile of tumor specimen C3L-05259-01 (profiled together with C3L-05259-05) from CPTAC case C3L-05259, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 82.7 years (30,224 days).
Specimen C3L-05259-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9c4c2e95-83f2-4187-bb5b-c999deebe294.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05259-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/9e86891f-2596-4cbc-a219-56bc9f18e052

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 5,710; copy number 2: 50,991; copy number 3: 1,683; copy number 4: 5; copy number 5: 121; copy number 6: 304; copy number 7: 75.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:7,380,534–7,484,263, 18 genes (within-gene range 0–1): TNK1, PLSCR3, TMEM256-PLSCR3, TMEM256, NLGN2, AC113189.2, SPEM1, SPEM2, SPEM3, AC113189.12, TMEM102, AC113189.1, FGF11, AC113189.3, AC113189.4, CHRNB1, ZBTB4, SLC35G6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 500 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–6,799,365, 161 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:6,952,625–7,104,482, 1 gene, copy number 6 (within-gene range 2–6): AC079804.3.
- chr7:7,078,302–16,888,885, 107 genes, copy number 6 (broad region; genes not listed).
- chr7:18,086,949–19,002,416, 1 gene, copy number 5 (within-gene range 2–5): HDAC9.
- chr7:18,807,993–22,727,613, 44 genes, copy number 5–7 (within-gene range 2–7): RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L, RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6.
- chr9:64,878,790–64,889,063, 2 genes, copy number 5: AC125634.1, RNU6-1293P.
- chr17:18,744,026–19,978,343, 79 genes, copy number 6 (broad region; genes not listed).
- chr17:20,185,082–20,633,259, 37 genes, copy number 5 (within-gene range 2–5): AC004702.1, RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2, USP32P3, SRP68P3, AC015818.9, AC015818.10, NOS2P3, LGALS9B, TNPO1P3, YWHAEP3, KRT16P5, KRT16P3, AC015818.7, KRT17P6, KRT17P7, AC015818.6, AC015818.2, AC015818.5, TBC1D3P3, AC015818.8, AC015818.1, AC015818.3, COTL1P2, AC015818.4, CDRT15L2, ZSWIM5P2, MEIS3P2, AC087499.3, AC087499.1, AC087499.4, LINC02088, AC087499.7.
- chr17:20,710,425–22,568,713, 68 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
